Gene-level copy-number profile of tumor specimen TCGA-13-0760-01A from TCGA case TCGA-13-0760, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 63.1 years (23,036 days).
Specimen TCGA-13-0760-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5b3a8dc0-c3ed-4616-8b9d-65673910c222.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0760-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2527c2e8-94f7-4a09-ad3b-4aa6d8faf161

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 7,604; copy number 2: 20,628; copy number 3: 18,986; copy number 4: 7,710; copy number 5: 2,787; copy number 6: 1,446; copy number 7: 119; copy number 8: 501; copy number 10: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0760-01A-01D-0356-01): tumor purity 0.81, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,153,284–188,890,671, 1 gene (within-gene range 0–2): LPP.
- chr3:188,562,238–190,167,651, 14 genes: LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3.
- chr4:78,180,866–78,182,046, 1 gene: SERBP1P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,404 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,325,525–156,082,465, 100 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:234,957,231–243,851,079, 160 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:30,408,170–43,223,227, 190 genes, copy number 6–7 (broad region; genes not listed).
- chr2:43,637,260–43,767,987, 1 gene, copy number 6 (within-gene range 3–6): PLEKHH2.
- chr2:43,772,120–63,827,843, 309 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr2:152,098,328–152,284,460, 5 genes, copy number 6: AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA.
- chr2:176,495,255–177,164,656, 14 genes, copy number 5 (within-gene range 3–5): LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1.
- chr2:177,138,699–177,138,797, 1 gene, copy number 5: RNA5SP112.
- chr3:138,889,255–154,329,819, 261 genes, copy number 5–6 (broad region; genes not listed).
- chr3:163,109,152–163,361,563, 1 gene, copy number 5 (within-gene range 4–5): LINC01192.
- chr3:163,455,568–175,810,548, 146 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:58,198–40,984,643, 635 genes, copy number 5 (broad region; genes not listed).
- chr5:132,875,395–138,575,675, 151 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:180,692,832–181,342,213, 46 genes, copy number 5: OR2AI1P, RNU1-17P, OR2Y1, MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:6,588,108–10,211,608, 46 genes, copy number 5 (within-gene range 4–5): LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1.
- chr6:125,674,353–127,681,555, 34 genes, copy number 5 (within-gene range 3–5): LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536.
- chr6:137,492,199–141,486,412, 57 genes, copy number 5: OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24, AL035446.1, AL357084.1, AL357080.1, AL355596.2, AL355596.1, RN7SKP106.
- chr6:150,827,663–151,621,193, 21 genes, copy number 6: PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P.
- chr7:83,355,154–89,338,528, 55 genes, copy number 5 (within-gene range 4–5): AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:108,470,417–122,144,255, 155 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:34,228,439–36,321,404, 19 genes, copy number 5: AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:96,239,398–102,124,907, 120 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:102,125,432–102,253,750, 5 genes, copy number 5: MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19.
- chr8:140,505,813–141,308,305, 17 genes, copy number 6 (within-gene range 4–6): AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2.
- chr9:60,914,407–71,446,904, 211 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:71,804,283–74,693,177, 33 genes, copy number 6: AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1, AL355674.1, RORB-AS1, RORB, AL137018.1.
- chr10:15,513,954–26,746,798, 165 genes, copy number 5–6 (broad region; genes not listed).
- chr11:46,396,414–47,905,607, 59 genes, copy number 6: AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2, AGBL2, FNBP4, Y_RNA, NUP160, AC021443.1, RNA5SP340, Y_RNA, YPEL5P2, AC023232.1.
- chr11:48,014,406–48,015,855, 1 gene, copy number 6: PTPRJ-AS1.
- chr11:69,048,932–82,970,584, 348 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr11:83,072,052–87,330,052, 76 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:66,767–2,812,902, 61 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:16,188,485–32,383,633, 279 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:55,392,622–55,872,939, 8 genes, copy number 5: MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr18:62,715,541–63,381,629, 7 genes, copy number 5: PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1.
- chr19:8,806,170–13,832,230, 291 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:37,735,833–40,898,282, 165 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:50,906,352–51,122,965, 21 genes, copy number 5: KLK4, PPIAP59, KLK5, AC011483.2, KLK6, AC011483.3, AC011483.1, KLK7, KLK8, AC011473.4, KLK9, KLK10, AC011473.2, KLK11, KLK12, AC011473.3, AC011473.1, KLK13, KLK14, CTU1, SIGLEC18P.
- chr20:1,629,152–4,431,732, 91 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:31,303,212–32,003,387, 37 genes, copy number 7: DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2.

Autosomal genes at a single copy (total copy number 1): 6,910. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
